Somatic mutation profile of tumor specimen 0DKIIC from CCDI case PBBXSM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,797 days).
Specimen 0DKIIC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 776023f4-9d02-41a3-9270-552567ad2f86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKIHQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95209dcf-d31e-4504-be1c-4afce3dbb65d

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 5270/5503 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 270/1102 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 272/308 reads (88%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ARAP3 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 69/605 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1433251800, COSV53354941; called by muse, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 176/998 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, varscan2
- DDX31 | c.2157C>G p.I719M | Missense Mutation (SNP) | VAF 112/962 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV64650691; called by muse, varscan2
- DNAH14 | c.6499G>A p.D2167N (on ENST00000445597; = p.D2820N on NM_001367479.1) | Missense Mutation (SNP) | VAF 544/1710 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1157442339; called by muse, varscan2
- F8 | c.156A>C p.R52S | Missense Mutation (SNP) | VAF 185/874 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.077); catalogued as CX138660; called by muse, varscan2
- SPTB | c.4912C>T p.R1638W | Missense Mutation (SNP) | VAF 230/403 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs368063704; called by muse, varscan2
- SUPT20HL2 | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 375/646 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs397832843; called by muse, varscan2
- UGT2B28 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 458/2105 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV59431017; called by muse, varscan2
- GFER | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 254/980 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- HPCA | c.282C>T p.R94= | Silent (SNP) | VAF 189/831 reads (23%) | catalogued as rs376799106, COSV65103330; called by muse, varscan2
- NEURL3 | c.183G>A p.V61= | Silent (SNP) | VAF 66/297 reads (22%) | called by muse, varscan2
- OPRK1 | c.990C>T p.Y330= | Silent (SNP) | VAF 134/549 reads (24%) | catalogued as rs77333617, COSV99653832; called by muse, varscan2
- POU6F1 | c.714G>A p.P238= | Silent (SNP) | VAF 49/376 reads (13%) | catalogued as rs916812193; called by muse, varscan2
- ALS2CL | c.2255+75G>T | Intron (SNP) | VAF 20/60 reads (33%) | called by muse, varscan2
- CLDN16 | chr3:190388120 A>G | 5'Flank (SNP) | VAF 80/690 reads (12%) | called by muse, varscan2
- DKK1 | c.*54C>A | 3'UTR (SNP) | VAF 46/160 reads (29%) | called by muse, varscan2
- EPHA3 | c.*100C>A | 3'UTR (SNP) | VAF 58/230 reads (25%) | called by muse, varscan2
- HBA1 | c.301-57G>T | Intron (SNP) | VAF 25/126 reads (20%) | called by muse, varscan2
